Somatic mutation profile of tumor specimen TARGET-20-PAPZYS-09A (aliquot TARGET-20-PAPZYS-09A-01D) from TARGET case TARGET-20-PAPZYS, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.5 years (2,357 days).
Specimen TARGET-20-PAPZYS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd011559-8972-472c-96dd-e01ee4c0a1f6.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PAPZYS-14A (Bone Marrow Normal), aliquot TARGET-20-PAPZYS-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69e6d6c4-de5a-4423-9498-ac1494dbf8a2

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.1775T>G p.V592G | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV54051432, COSV54058572, COSV54074139; called by muse, mutect2, varscan2
- TRIM24 | c.2503G>A p.G835R (on ENST00000343526 / NM_015905.3; = p.G801R on NM_003852.4) | Missense Mutation (SNP) | VAF 85/200 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100630755, COSV100630950; called by muse, mutect2, varscan2
- HOXA5 | c.619A>G p.T207A | Missense Mutation (SNP) | VAF 83/184 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- RUNX1 | c.377_385del p.N126_A129delinsT (on ENST00000344691 / NM_001001890.3; = p.N153_A156delinsT on NM_001754.5) | In Frame Del (DEL) | VAF 59/166 reads (36%) | called by mutect2, pindel, varscan2
